Somatic mutation profile of tumor specimen ALCH-B05D-TTP1-A (aliquot ALCH-B05D-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B05D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.8 years (21,470 days).
Specimen ALCH-B05D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b7ef6ed-2d0e-480d-97bc-d4aeda6f091f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B05D-NB1-A (Blood Derived Normal), aliquot ALCH-B05D-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5cd8c04-d663-4e72-9744-26be53db6fac

The open-access MAF lists 225 somatic variants for this specimen: 160 protein-altering or splice-affecting, 40 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 40, Intron 14, Nonsense Mutation 12, Frame Shift Del 7, Splice Site 5, 3'UTR 4, RNA 4, Frame Shift Ins 3, Splice Region 3, 5'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 69/287 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC11 | c.1614G>T p.M538I | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1481930924, COSV62322518; called by muse, mutect2, varscan2
- ACE | c.168C>A p.S56R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.575); catalogued as rs868605010; called by muse, mutect2, varscan2
- ANK2 | c.6769C>A p.Q2257K | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs747833774, COSV52157783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBX | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs773183935; called by muse, mutect2, varscan2
- BNC1 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs747572517; called by muse, mutect2, varscan2
- C9 | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 42/266 reads (16%) | catalogued as COSV104373936; called by muse, varscan2
- CCDC54 | c.513C>A p.Y171* | Nonsense Mutation (SNP) | VAF 20/156 reads (13%) | catalogued as COSV53759766; called by muse, mutect2, varscan2
- COL4A2 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV64633347; called by muse, mutect2, varscan2
- CSMD3 | c.9518G>A p.C3173Y (on ENST00000297405 / NM_001363185.1; = p.C3004Y on NM_052900.3) | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99835055; called by muse, mutect2, varscan2
- DGKB | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as COSV99338468; called by muse, mutect2, varscan2
- EN1 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV54631473; called by muse, mutect2, varscan2
- ENPEP | c.1158G>T p.R386S | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1263451725, COSV54448784; called by muse, mutect2, varscan2
- EPHB4 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs780180360; called by muse, mutect2, varscan2
- GPR139 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs1425613899; called by muse, mutect2, varscan2
- HAPLN1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs991685894; called by muse, mutect2
- IBSP | c.435del p.E146Rfs*31 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as COSV99883383; called by mutect2, pindel
- IGHE | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.356); catalogued as rs782416864; called by muse, mutect2, varscan2
- KANSL1L | c.1568A>C p.D523A | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.651); catalogued as COSV55996865; called by muse, mutect2, varscan2
- KCNA1 | c.339C>G p.F113L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as rs1224619978; called by muse, mutect2, varscan2
- LILRB4 | c.560C>A p.S187* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as COSV54408133; called by muse, varscan2
- LRP1B | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67275891; called by muse, mutect2, varscan2
- LTBP3 | c.1274G>C p.R425P | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57240744; called by muse, mutect2, varscan2
- MEGF10 | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV99174914; called by muse, mutect2, varscan2
- MGAT4C | c.1085G>A p.S362N | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs1472660511; called by muse, mutect2, varscan2
- MXRA5 | c.2338C>A p.P780T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54225452; called by muse, mutect2, varscan2
- NAP1L2 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV65172200; called by muse, mutect2, varscan2
- NAV3 | c.6490C>A p.P2164T (on ENST00000397909 / NM_001024383.2; = p.P2142T on NM_014903.6) | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV57121880; called by muse, mutect2, varscan2
- NCR1 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs756166596, COSV52555430; called by muse, varscan2
- ONECUT1 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59951103; called by muse, mutect2, varscan2
- OR2B11 | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV100276666, COSV59511318; called by muse, varscan2
- OR2L3 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs765931236, COSV63455451; called by muse, mutect2, varscan2
- OR2M7 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV100522765, COSV58739121; called by muse, mutect2, varscan2
- OR4L1 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV59849785; called by muse, mutect2, varscan2
- PCDHGA9 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.139); catalogued as rs758295115; called by muse, mutect2, varscan2
- PHLPP1 | c.1919G>T p.S640I | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV53035512; called by muse, varscan2
- PLEC | c.793G>T p.G265C (on ENST00000322810 / NM_201380.4; = p.G155C on NM_000445.5) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59606586; called by muse, mutect2, varscan2
- POM121L12 | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV68692936; called by mutect2, varscan2
- POTED | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.788); catalogued as COSV100202960, COSV100203242; called by muse, mutect2, varscan2
- PSD2 | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); catalogued as COSV51197255; called by muse, mutect2, varscan2
- RFPL4B | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV71437506; called by muse, mutect2, varscan2
- RNF38 | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99425440; called by muse, mutect2
- SEMA6A | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV57307631, COSV57312588; called by muse, mutect2, varscan2
- SHPRH | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.13); catalogued as COSV51613434; called by muse, varscan2
- SLC25A31 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); catalogued as rs887983958; called by muse, mutect2, varscan2
- SLC45A2 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.044); catalogued as COSV56874814; called by muse, mutect2, varscan2
- SNRNP40 | c.655G>T p.V219F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV55280077; called by muse, mutect2, varscan2
- STARD9 | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs764135772; called by muse, mutect2, varscan2
- UBR5 | c.3549G>T p.W1183C | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55300944; called by muse, mutect2, varscan2
- UNC80 | c.6330G>T p.K2110N | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55909606; called by muse, mutect2, varscan2
- VHL | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); catalogued as COSV56544143; called by muse, mutect2, varscan2
- VRTN | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.134); catalogued as COSV99832304; called by muse, mutect2, varscan2
- ZFHX4 | c.1184C>G p.P395R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as COSV51489874; called by muse, mutect2, varscan2
- ZFPM2 | c.2596G>T p.V866L | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs371740091, COSV101023217; called by muse, mutect2, varscan2
- ZNF679 | c.390C>A p.S130R | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV55377054; called by muse, mutect2, varscan2
- ABCB5 | c.676A>C p.R226= | Splice Region (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- ABCB5 | c.677G>T p.R226M | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.794); called by muse, varscan2
- ACAP2 | c.1871A>T p.E624V | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- ACTRT2 | c.357C>A p.N119K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- ADAM30 | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADCY8 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD18B | c.1967A>G p.H656R | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ARHGAP36 | c.497del p.F166Sfs*61 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | called by mutect2, pindel, varscan2
- ASTL | c.338-1G>A p.X113_splice | Splice Site (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- ASXL3 | c.1961C>T p.S654F | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASXL3 | c.3181G>T p.A1061S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BCHE | c.1203C>A p.Y401* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | called by muse, varscan2
- BSCL2 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CARNMT1 | c.426+4T>C | Splice Region (SNP) | VAF 11/66 reads (17%) | called by mutect2, varscan2
- CD6 | c.1876G>T p.G626W | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTNAP5 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL21A1 | c.1651-2A>T p.X551_splice | Splice Site (SNP) | VAF 41/196 reads (21%) | called by muse, varscan2
- CROCC2 | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CSMD3 | c.3953T>G p.L1318R (on ENST00000297405 / NM_001363185.1; = p.L1214R on NM_052900.3) | Missense Mutation (SNP) | VAF 74/404 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CTNNBL1 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTNND2 | c.3001C>A p.H1001N | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CUL7 | c.2113C>T p.H705Y | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLGAP3 | c.122T>C p.F41S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DPY19L3 | c.537G>C p.W179C | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DPYS | c.1349C>A p.A450D | Missense Mutation (SNP) | VAF 35/332 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMC7 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- EPHA6 | c.3001C>A p.Q1001K | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FAP | c.893G>T p.W298L | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- FSIP2 | c.4387A>G p.R1463G | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HES1 | c.26del p.N9Ifs*42 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel
- HSPB3 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 47/314 reads (15%) | called by muse, mutect2, varscan2
- IGKV3D-11 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IQGAP2 | c.2478C>A p.N826K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ITGA8 | c.1028C>G p.P343R | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITGB2 | c.1169G>T p.R390M (on ENST00000302347; = p.R366M on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- KIF20B | c.1502A>G p.D501G | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- KIF4A | c.1072G>T p.V358L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- KTN1 | c.2626A>G p.M876V | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- LIAS | c.596A>T p.D199V (on ENST00000261434 / NM_001363700.2; = p.D302V on NM_006859.4) | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LPAR4 | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- LRRTM4 | c.828_829insA p.P277Tfs*51 | Frame Shift Ins (INS) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- LTBP2 | c.4519C>G p.P1507A | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARK1 | c.424+1dup | Frame Shift Ins (INS) | VAF 18/130 reads (14%) | called by mutect2, pindel, varscan2
- MARVELD3 | c.1093A>C p.I365L | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MCM3AP | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- MDGA2 | c.2350G>T p.V784F (on ENST00000399232 / NM_001113498.2; = p.V486F on NM_182830.4) | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MDN1 | c.653del p.F218Sfs*3 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- MEOX2 | c.114C>A p.Y38* | Nonsense Mutation (SNP) | VAF 36/255 reads (14%) | called by muse, mutect2, varscan2
- NBEA | c.1068G>T p.M356I | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NFASC | c.582C>A p.N194K (on ENST00000339876 / NM_001378329.1; = p.N188K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NRIP1 | c.1201A>T p.R401* | Nonsense Mutation (SNP) | VAF 37/268 reads (14%) | called by muse, mutect2, varscan2
- NSUN5 | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- NUP205 | c.3531A>G p.K1177= | Splice Region (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- NUTM1 | c.1130G>T p.W377L | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OCA2 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR13G1 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR56A1 | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PAG1 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PAPPA2 | c.1427C>A p.P476Q | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PAX6 | c.148A>G p.N50D | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHA4 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHB12 | c.1992C>G p.D664E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- PHF12 | c.291G>C p.W97C | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PIK3CA | c.2885T>C p.I962T | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- POLR2A | c.3190G>T p.A1064S | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- PPDPFL | c.123A>C p.K41N | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PPFIA2 | c.2077C>A p.L693M | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRRC2C | c.4207G>T p.A1403S (on ENST00000367742; = p.A1401S on NM_015172.4) | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PUM2 | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2
- R3HDML | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, varscan2
- RAB11FIP2 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 52/362 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.413); called by muse, varscan2
- RAB3IP | c.1430G>T p.*477Lext*8 (on ENST00000550536 / NM_175623.4; = p.*461Lext*8 on NM_022456.5) | Nonstop Mutation (SNP) | VAF 28/242 reads (12%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- RASL12 | c.174_180del p.S58Rfs*11 | Frame Shift Del (DEL) | VAF 17/173 reads (10%) | called by mutect2, pindel
- RBM23 | c.846C>G p.I282M (on ENST00000359890 / NM_001077351.2; = p.I266M on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RESF1 | c.3887A>C p.K1296T | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, varscan2
- SCG3 | c.136-2A>T p.X46_splice | Splice Site (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- SCN7A | c.4488G>C p.M1496I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SERPINB12 | c.244-1G>T p.X82_splice | Splice Site (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- SHISAL1 | c.448G>T p.G150W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- SIGLEC14 | c.576del p.T193Pfs*23 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, varscan2
- SLC22A7 | c.550del p.V184Cfs*13 (on ENST00000372585 / NM_153320.2; = p.V182Cfs*13 on NM_006672.3) | Frame Shift Del (DEL) | VAF 16/149 reads (11%) | called by mutect2, pindel, varscan2
- SLC35C1 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); called by mutect2, varscan2
- SLC4A8 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPEG | c.4600G>T p.V1534L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SPON1 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, varscan2
- TCERG1 | c.2375G>A p.G792D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.41); called by muse, mutect2
- TDRD15 | c.2840C>A p.S947Y | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TDRD3 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 72/263 reads (27%) | called by muse, mutect2, varscan2
- TEX13B | c.321G>C p.L107F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM9 | c.2045C>A p.A682E | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSC2 | c.4378G>C p.G1460R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSPAN9 | c.92_106del p.G31_S35del | In Frame Del (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel, varscan2
- UNC79 | c.1694G>T p.C565F (on ENST00000393151 / NM_001346218.2; = p.C388F on NM_020818.5) | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP36 | c.828+1del p.X276_splice | Splice Site (DEL) | VAF 27/195 reads (14%) | called by mutect2, pindel, varscan2
- VGLL3 | c.263G>T p.C88F | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- VPS13D | c.2758C>G p.Q920E | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- XKR4 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- ZNF286A | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2, varscan2
- ZNF471 | c.1442A>T p.H481L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF530 | c.299dup p.R101Efs*8 | Frame Shift Ins (INS) | VAF 16/145 reads (11%) | called by mutect2, varscan2
- ZNF548 | c.572A>T p.Q191L | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- ZNF616 | c.646A>T p.N216Y | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ZNF778 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); called by muse, varscan2
- ZSCAN18 | c.517C>A p.L173I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, varscan2
- ABI3BP | c.2745C>T p.V915= | Silent (SNP) | VAF 28/270 reads (10%) | called by muse, mutect2
- ADAMTS10 | c.798C>T p.A266= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs1425937282, COSV54356823; called by muse, mutect2, varscan2
- ARID4A | c.219A>T p.G73= | Silent (SNP) | VAF 28/234 reads (12%) | catalogued as rs1368013321; called by muse, mutect2, varscan2
- BARD1 | c.169C>T p.L57= | Silent (SNP) | VAF 44/327 reads (13%) | catalogued as rs1559441908; called by muse, mutect2, varscan2
- CES2 | c.1552C>T p.L518= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- DGKQ | c.2376C>T p.S792= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- DOCK8 | c.3753A>T p.G1251= | Silent (SNP) | VAF 43/331 reads (13%) | called by muse, mutect2, varscan2
- FGD2 | c.1059C>T p.P353= | Silent (SNP) | VAF 24/169 reads (14%) | called by muse, mutect2, varscan2
- GLRB | c.651A>T p.S217= | Silent (SNP) | VAF 38/202 reads (19%) | catalogued as COSV52418986; called by muse, mutect2, varscan2
- GPR45 | c.852C>G p.S284= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs1408619721, COSV99307302; called by muse, mutect2
- HSPB3 | c.372G>T p.V124= | Silent (SNP) | VAF 47/318 reads (15%) | called by muse, mutect2, varscan2
- IGFBP3 | c.165C>A p.P55= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- KCNK16 | c.447C>A p.A149= | Silent (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- KIAA1549L | c.921C>G p.T307= (on ENST00000321505; = p.T604= on NM_012194.3) | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV55771470, COSV99683389; called by muse, mutect2
- KLHL4 | c.624T>C p.A208= | Silent (SNP) | VAF 29/91 reads (32%) | called by muse, mutect2, varscan2
- KRT3 | c.99C>A p.A33= | Silent (SNP) | VAF 18/145 reads (12%) | called by muse, mutect2, varscan2
- LAMA4 | c.201C>T p.C67= | Silent (SNP) | VAF 40/292 reads (14%) | called by muse, mutect2, varscan2
- LRP1B | c.7483C>A p.R2495= | Silent (SNP) | VAF 26/203 reads (13%) | catalogued as COSV67184084; called by muse, mutect2, varscan2
- MYO15A | c.2379G>T p.A793= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV52754796; called by muse, mutect2, varscan2
- NIPBL | c.2856G>T p.A952= | Silent (SNP) | VAF 39/263 reads (15%) | called by muse, mutect2, varscan2
- NLRP3 | c.2580G>T p.V860= | Silent (SNP) | VAF 84/285 reads (29%) | catalogued as rs1294489789, COSV60228390; called by muse, mutect2, varscan2
- NT5C1B | c.912C>A p.P304= (on ENST00000359846 / NM_001199086.2; = p.P244= on NM_033253.4) | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2
- NYAP2 | c.117G>A p.A39= | Silent (SNP) | VAF 79/355 reads (22%) | catalogued as rs916212363, COSV56014602; called by muse, mutect2, varscan2
- OBSCN | c.10344G>A p.L3448= | Silent (SNP) | VAF 32/268 reads (12%) | called by muse, mutect2, varscan2
- OR11L1 | c.870C>T p.Y290= | Silent (SNP) | VAF 30/220 reads (14%) | catalogued as rs761262152; called by muse, mutect2, varscan2
- PCNT | c.4782G>A p.G1594= | Silent (SNP) | VAF 41/285 reads (14%) | called by muse, mutect2, varscan2
- PIGQ | c.1146G>T p.T382= | Silent (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- PITX1 | c.120C>A p.R40= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV99530763; called by muse, mutect2, varscan2
- PROKR1 | c.207G>T p.L69= | Silent (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- RAB3IL1 | c.993G>T p.R331= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- RFLNA | c.471A>C p.P157= (on ENST00000546355 / NM_001365156.1; = p.P76= on NM_181709.4) | Silent (SNP) | VAF 24/144 reads (17%) | called by muse, mutect2, varscan2
- SELENOV | c.702G>A p.L234= | Silent (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- SYNM | c.33G>A p.E11= | Silent (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- TCERG1 | c.786G>T p.T262= | Silent (SNP) | VAF 35/198 reads (18%) | catalogued as COSV57041785; called by muse, mutect2, varscan2
- TENT4B | c.276C>A p.G92= (on ENST00000561678 / NM_001365323.2; = p.G77= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- THSD7B | c.532C>A p.R178= | Silent (SNP) | VAF 41/192 reads (21%) | called by muse, mutect2, varscan2
- TRPM1 | c.2127G>A p.S709= | Silent (SNP) | VAF 68/462 reads (15%) | catalogued as rs769533569, COSV56641667; called by muse, mutect2, varscan2
- TSPAN32 | c.537G>A p.A179= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs200478299; called by muse, mutect2, varscan2
- UBE2V2 | c.405A>T p.P135= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- ZFPM2 | c.2595G>A p.K865= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as rs748031973, COSV65875048; called by muse, mutect2, varscan2
- AC125421.1 | n.325-261C>A | Intron (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2
- AL109984.1 | n.186+1346G>C | Intron (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- BRD9 | c.1525+1191G>T | Intron (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- C11orf68 | chr11:65918984 G>A | 5'Flank (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- COL25A1 | c.1845+70T>A | Intron (SNP) | VAF 52/282 reads (18%) | called by muse, mutect2, varscan2
- CSNK1D | c.1198-1159G>T | Intron (SNP) | VAF 39/177 reads (22%) | called by muse, mutect2, varscan2
- DNAI2 | c.1347+151C>G | Intron (SNP) | VAF 25/164 reads (15%) | called by muse, mutect2, varscan2
- FAM27E5 | n.161C>T | RNA (SNP) | VAF 8/91 reads (9%) | called by muse, mutect2
- FLVCR2 | c.*21A>T | 3'UTR (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- FOLH1B | n.1358T>C | RNA (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2
- FZD7 | c.*1G>A | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, varscan2
- GADL1 | c.-27G>T | 5'UTR (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.291+11142A>G | Intron (SNP) | VAF 10/226 reads (4%) | catalogued as COSV61847083; called by muse, mutect2
- KATNIP | c.540+5992G>T | Intron (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
- LINC00587 | n.345C>A | RNA (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18489C>A | Intron (SNP) | VAF 10/40 reads (25%) | called by muse, varscan2
- LINC01551 | n.1254+18551A>G | Intron (SNP) | VAF 27/103 reads (26%) | called by muse, varscan2
- MASP1 | c.1304-5214C>T | Intron (SNP) | VAF 28/197 reads (14%) | called by muse, mutect2, varscan2
- MIR572 | n.27G>A | RNA (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- MMGT1 | c.-108G>T | 5'UTR (SNP) | VAF 23/65 reads (35%) | catalogued as rs1206212530; called by muse, mutect2, varscan2
- OVCH1 | c.2280+119C>T | Intron (SNP) | VAF 15/62 reads (24%) | catalogued as rs778897265; called by muse, mutect2, varscan2
- PROP1 | c.*44C>T | 3'UTR (SNP) | VAF 6/31 reads (19%) | catalogued as rs568853711; called by muse, mutect2, varscan2
- RGS4 | c.*74G>T | 3'UTR (SNP) | VAF 28/194 reads (14%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12719C>A | Intron (SNP) | VAF 12/64 reads (19%) | called by muse, varscan2
- TXNIP | c.251-60A>G | Intron (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
